Gene-level copy-number profile of tumor specimen TCGA-MN-A4N4-01A from TCGA case TCGA-MN-A4N4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.2 years (20,888 days).
Specimen TCGA-MN-A4N4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.2ece0519-0e35-4c26-af50-eb3f429aa37d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MN-A4N4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c5d09ab6-7264-4d43-85f4-14f7bdff78d2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 835; copy number 2: 5,315; copy number 3: 14,545; copy number 4: 20,605; copy number 5: 8,337; copy number 6: 7,108; copy number 7: 1,131; copy number 8: 552; copy number 9: 167; copy number 10: 635; copy number 11: 112; copy number 12: 164; copy number 13: 140; copy number 14: 12; copy number 15: 139; copy number 21: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MN-A4N4-01A-12D-A24O-01): tumor purity 0.34, ploidy 4.12, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,384 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:239,386,565–246,507,312, 115 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr2:195,003,711–195,026,370, 1 gene, copy number 9 (within-gene range 4–9): AC010983.1.
- chr5:10,352,701–45,895,970, 491 genes, copy number 10–15 (broad region; genes not listed).
- chr8:96,645,242–97,149,654, 3 genes, copy number 10 (within-gene range 6–10): CPQ, AP003117.2, AP003117.1.
- chr12:31,876,969–44,503,596, 142 genes, copy number 9–11 (broad region; genes not listed).
- chr12:58,394,596–59,130,875, 8 genes, copy number 11: AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1.
- chr12:61,600,067–64,162,217, 50 genes, copy number 10: DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1, DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4, SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2, AC025576.3, AC025576.2, AC025576.1.
- chr13:71,437,966–114,337,626, 547 genes, copy number 10 (broad region; genes not listed).
- chr18:26,421,139–28,177,946, 27 genes, copy number 14–21: LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.

Autosomal genes at a single copy (total copy number 1): 773. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
